Somatic mutation profile of tumor specimen TCGA-AA-3502-01A (aliquot TCGA-AA-3502-01A-01D-1408-10) from TCGA case TCGA-AA-3502, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 73.2 years (26,724 days).
Specimen TCGA-AA-3502-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 545ec2db-4ec8-4bbf-84c7-67445e6c94b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3502-11A (Solid Tissue Normal), aliquot TCGA-AA-3502-11A-01D-1408-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e8b588f-fe78-46f0-a742-36fb70d2bcf3

The open-access MAF lists 206 somatic variants for this specimen: 150 protein-altering or splice-affecting, 53 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 132, Silent 53, Nonsense Mutation 8, Frame Shift Del 4, RNA 3, Splice Region 2, Frame Shift Ins 2, Translation Start Site 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 22/70 reads (31%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ATM | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 33/86 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138398778, CM0910483, COSV53723836, COSV53775938; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ERBB2 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 34/78 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as rs1057519862, COSV54062926; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- GNAS | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 28/67 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs121913495, CM158823, COSV55670349, COSV55671845; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 38/105 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TGM1 | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as rs773303931, CM077640; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756179835, COSV59383178; called by muse, mutect2, varscan2
- ABCB5 | c.1381C>T p.R461* (on ENST00000404938 / NM_001163941.2; = p.R16* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 35/106 reads (33%) | catalogued as rs761699207, COSV51703279; called by muse, mutect2, varscan2
- AC023055.1 | c.1460T>C p.L487P | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100278455; called by muse, mutect2, varscan2
- ACSBG1 | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.85); PolyPhen benign (0.006); catalogued as rs1037796617, COSV51903508; called by muse, mutect2, varscan2
- ADAMTS16 | c.1427G>A p.R476H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777610990, COSV56978893; called by muse, mutect2, varscan2
- ADAMTS20 | c.1060G>T p.A354S | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.926); catalogued as COSV67126616; called by muse, mutect2, varscan2
- ADAMTSL3 | c.160C>A p.Q54K | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.824); catalogued as COSV54437131; called by muse, mutect2, varscan2
- ALDH3B2 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs777931713, COSV62427531; called by muse, mutect2, varscan2
- ALPK1 | c.3692G>C p.R1231P | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.913); catalogued as COSV51582075; called by muse, mutect2, varscan2
- ANAPC1 | c.4366A>T p.T1456S | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV100594548; called by muse, mutect2, varscan2
- ANK3 | c.8234G>A p.R2745K | Missense Mutation (SNP) | VAF 83/202 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55045129; called by muse, mutect2, varscan2
- ANTXR1 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as rs1245377168, COSV58009436; called by muse, mutect2, varscan2
- APC | c.4240G>T p.V1414L | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV57321918, COSV57322665, COSV57326384; called by muse, mutect2, varscan2
- APC | c.4241T>G p.V1414G | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.176); catalogued as COSV57325736, COSV57326393; called by muse, mutect2, varscan2
- APOA5 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV57062352; called by muse, mutect2, varscan2
- ARID5A | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs753830076, COSV62590744; called by muse, mutect2, varscan2
- ARL11 | c.80C>T p.T27M | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as rs1394373519, COSV56290674; called by muse, mutect2, varscan2
- ATOH1 | c.575del p.D192Afs*111 | Frame Shift Del (DEL) | VAF 28/69 reads (41%) | catalogued as COSV60037453; called by mutect2, pindel, varscan2
- ATP1B3 | c.625A>T p.M209L | Missense Mutation (SNP) | VAF 54/98 reads (55%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV53948952; called by muse, mutect2, varscan2
- ATR | c.20A>T p.E7V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV63384099; called by muse, mutect2, varscan2
- AUTS2 | c.3439G>A p.G1147S | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.029); catalogued as rs747086851, COSV100715309; called by muse, mutect2, varscan2
- AWAT1 | c.244T>C p.F82L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs111373170; called by mutect2, varscan2
- BMP5 | c.1029T>G p.D343E | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV63701125, COSV63707406; called by muse, mutect2, varscan2
- C1R | c.1923G>T p.K641N (on ENST00000536053 / NM_001354346.2; = p.K627N on NM_001733.7) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.076); catalogued as COSV101605607, COSV73383035; called by muse, mutect2, varscan2
- C6orf118 | c.859C>G p.L287V | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.273); catalogued as rs758904891, COSV57812619; called by muse, mutect2, varscan2
- CACNA1B | c.2920G>A p.E974K | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.718); catalogued as COSV99495615; called by muse, mutect2, varscan2
- CACNA2D3 | c.1610C>T p.P537L | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748459234, COSV55516275; called by muse, mutect2, varscan2
- CAMTA1 | c.4783C>T p.R1595W | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759514197, COSV100346816; called by muse, mutect2, varscan2
- CBX6 | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.888); catalogued as rs998306460, COSV53320305; called by muse, mutect2, varscan2
- CDR1 | c.625dup p.S209Ffs*17 | Frame Shift Ins (INS) | VAF 91/141 reads (65%) | catalogued as rs779058892; called by mutect2, pindel, varscan2
- CELSR3 | c.8752C>T p.R2918W | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs747576733, COSV50840393; called by muse, mutect2, varscan2
- CHKB | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV56415147; called by muse, mutect2, varscan2
- CHST1 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.625); catalogued as COSV57321895; called by muse, mutect2, varscan2
- CHST13 | c.932T>C p.I311T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV60041373; called by muse, mutect2
- CLEC18B | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1254994146; called by mutect2, varscan2
- CMIP | c.1654G>T p.G552C (on ENST00000537098 / NM_198390.2; = p.G458C on NM_030629.3) | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67697128; called by muse, mutect2, varscan2
- COL5A2 | c.1613C>A p.P538Q | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.705); catalogued as COSV66407276; called by muse, mutect2, varscan2
- CPE | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs756392535, COSV101291545, COSV68579227; called by muse, mutect2, varscan2
- CPSF2 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV54097085; called by muse, mutect2, varscan2
- CRTAC1 | c.1816G>A p.V606M | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs772062581, COSV53997647; called by muse, mutect2, varscan2
- CXCR5 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.994); catalogued as COSV52682123; called by muse, mutect2, varscan2
- DCLK1 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1237880518, COSV55172983; called by muse, mutect2, varscan2
- DENND5A | c.910T>G p.C304G | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100064173; called by muse, mutect2, varscan2
- DLC1 | c.4325G>T p.C1442F (on ENST00000276297 / NM_001348081.2; = p.C1005F on NM_006094.5) | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV52291114; called by muse, mutect2, varscan2
- DLGAP2 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1423353722, COSV101423105, COSV70094440; called by muse, mutect2, varscan2
- DNAH5 | c.2207C>A p.T736N | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.062); catalogued as COSV99445858; called by muse, mutect2, varscan2
- DPYSL3 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1437159047, COSV58324181; called by muse, mutect2, varscan2
- DUSP16 | c.1438C>T p.Q480* | Nonsense Mutation (SNP) | VAF 8/84 reads (10%) | catalogued as COSV53807641; called by muse, mutect2
- ENPP6 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.668); catalogued as rs775345484, COSV57065810; called by muse, mutect2, varscan2
- EPB41L5 | c.473C>T p.T158I | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV55349258; called by muse, mutect2, varscan2
- EPHA10 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs868136274, COSV57621521, COSV57628166; called by muse, mutect2, varscan2
- EVC2 | c.1180G>T p.D394Y | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.116); catalogued as COSV100186837, COSV60388183; called by muse, mutect2, varscan2
- F2RL3 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.96); PolyPhen benign (0.035); catalogued as rs775233424, COSV50185181; called by muse, mutect2, varscan2
- FAT3 | c.8269G>A p.V2757I | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs374977464; called by muse, mutect2, varscan2
- FBH1 | c.367C>T p.R123W (on ENST00000362091 / NM_178150.3; = p.R174W on NM_032807.4) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1312625993, COSV62981656; called by muse, mutect2, varscan2
- FGF3 | c.588T>G p.S196R | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV100490112, COSV61926559; called by muse, mutect2, varscan2
- FGF3 | c.587G>T p.S196I | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.039); catalogued as COSV100490113, COSV61926844; called by muse, mutect2, varscan2
- FMR1NB | c.518G>T p.C173F | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63272665; called by muse, mutect2, varscan2
- FN1 | c.1783G>C p.G595R | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60547001; called by muse, mutect2, varscan2
- GOLGB1 | c.6268G>A p.E2090K | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100510400; called by muse, mutect2, varscan2
- GRM4 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1431545411, COSV65210816; called by muse, mutect2, varscan2
- GUCY1A1 | c.1332G>T p.E444D | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as COSV56651838, COSV99637255; called by muse, mutect2, varscan2
- HSD17B6 | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.808); catalogued as COSV59107153; called by muse, mutect2, varscan2
- ICAM1 | c.1468G>A p.A490T | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs775418785, COSV53423638; called by muse, mutect2, varscan2
- IFT43 | c.311C>T p.P104L (on ENST00000314067 / NM_001102564.3; = p.P109L on NM_052873.3) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144547737, COSV53136710; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGHA2 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs573262638; called by muse, mutect2, varscan2
- ING1 | c.1108G>T p.D370Y | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV58166764, COSV58172279; called by muse, mutect2, varscan2
- IPO7 | c.2413C>T p.R805C | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs773555364, COSV65684279; called by muse, mutect2, varscan2
- ITGAX | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs146081281; called by muse, mutect2, varscan2
- ITPRIPL1 | c.617G>A p.R206H (on ENST00000439118 / NM_001008949.3; = p.R214H on NM_178495.6) | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs150184854; called by muse, mutect2, varscan2
- JAKMIP1 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV51522648; called by muse, mutect2, varscan2
- KAT14 | c.1256A>G p.E419G | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.326); catalogued as COSV66606748; called by muse, mutect2, varscan2
- KCNB1 | c.194C>T p.T65M | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65566190; called by muse, mutect2, varscan2
- KCNH3 | c.1186A>G p.I396V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.262); catalogued as COSV99234821; called by muse, mutect2, varscan2
- KMT2E | c.3499C>T p.R1167C | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs377533573; called by muse, mutect2, varscan2
- KPNA6 | c.474G>T p.Q158H | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV65359326; called by muse, mutect2, varscan2
- KPNA6 | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 23/55 reads (42%) | catalogued as COSV65359333; called by muse, varscan2
- KRT7 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs762446937, COSV100081377; called by muse, mutect2
- LPA | c.5072C>T p.T1691M | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.189); catalogued as rs757188741, COSV60314570; called by muse, mutect2, varscan2
- LPXN | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.992); catalogued as rs1214329253, COSV67716100; called by muse, mutect2, varscan2
- LRFN5 | c.2096C>G p.P699R | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); catalogued as COSV53244013, COSV53265932; called by muse, mutect2, varscan2
- MAGEA6 | c.813C>G p.F271L | Missense Mutation (SNP) | VAF 117/129 reads (91%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs1556827048, COSV100262885, COSV61448677; called by muse, mutect2, varscan2
- MAGEC1 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV53568319; called by muse, mutect2, varscan2
- MAPK12 | c.693C>T p.H231= | Splice Region (SNP) | VAF 12/27 reads (44%) | catalogued as COSV53132013; called by muse, mutect2, varscan2
- MCF2L | c.452G>A p.R151H (on ENST00000375608; = p.R119H on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs767778805, COSV65048552; called by muse, mutect2, varscan2
- METRNL | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as rs776659125, COSV60759772; called by muse, mutect2, varscan2
- MEX3B | c.1487C>T p.S496L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.866); catalogued as COSV61664089; called by muse, mutect2, varscan2
- MEX3C | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs754601042, COSV68529595; called by muse, mutect2, varscan2
- MGAT3 | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.271); catalogued as COSV57864135; called by muse, mutect2, varscan2
- MROH7 | c.2710C>T p.R904C | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.804); catalogued as rs776173828, COSV59868801; called by muse, mutect2
- MYO16 | c.2276G>A p.C759Y | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51778481, COSV99194771; called by muse, mutect2, varscan2
- NBAS | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs781438518, COSV99867699, COSV99870858; called by muse, mutect2, varscan2
- NCR1 | c.636C>T p.G212= | Splice Region (SNP) | VAF 23/98 reads (23%) | catalogued as rs770811879, COSV52555460, COSV99401131; called by muse, mutect2, varscan2
- NELL2 | c.2431C>T p.Q811* | Nonsense Mutation (SNP) | VAF 52/97 reads (54%) | catalogued as COSV61569490; called by muse, mutect2, varscan2
- NEUROD4 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139282092; called by muse, mutect2, varscan2
- NLRP4 | c.2905C>T p.L969F | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.055); catalogued as COSV56708213; called by muse, mutect2, varscan2
- NLRP7 | c.1225C>T p.R409W | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as rs746094829, COSV60171315, COSV60180552; called by muse, mutect2, varscan2
- NR2E1 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.625); catalogued as COSV64561439; called by muse, mutect2, varscan2
- OR8J3 | c.275C>T p.T92I | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56879469; called by muse, mutect2, varscan2
- PCDH10 | c.3074C>T p.T1025M | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.548); catalogued as rs747022854, COSV52087382; called by muse, mutect2, varscan2
- PCDH17 | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.807); catalogued as rs1566212693, COSV100931464; called by muse, mutect2, varscan2
- PCDHA10 | c.1505C>T p.S502L | Missense Mutation (SNP) | VAF 65/149 reads (44%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV100248191; called by muse, mutect2, varscan2
- PCM1 | c.3190C>G p.Q1064E | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61514818; called by muse, mutect2, varscan2
- PEG3 | c.2894G>A p.R965Q | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.728); catalogued as rs765309826, COSV55623550; called by muse, mutect2, varscan2
- PLCH2 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs750368114, COSV53939371; called by muse, mutect2, varscan2
- PPM1K | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.109); catalogued as rs370483637; called by muse, mutect2, varscan2
- PRDX6 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV100458415; called by muse, mutect2, varscan2
- PRKAR1B | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs1562611130, COSV64317807; called by muse, mutect2, varscan2
- PRKCH | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV60645882; called by muse, mutect2, varscan2
- PTER | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as rs370033967; called by muse, mutect2, varscan2
- PXDNL | c.3956G>A p.R1319H | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1309624471, COSV62478813, COSV62502615; called by muse, mutect2, varscan2
- RARS1 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51562086; called by muse, mutect2, varscan2
- ROBO1 | c.3877C>T p.R1293W | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as rs370726850; called by muse, mutect2, varscan2
- ROR1 | c.450T>G p.F150L | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as COSV64284113; called by muse, mutect2, varscan2
- RRP1B | c.1427G>A p.R476Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs139787661, COSV100513092; called by muse, mutect2, varscan2
- RYR1 | c.1108G>A p.V370M | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.481); catalogued as rs537344365, COSV62089560; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SALL2 | c.1801C>T p.R601W | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs768526871, COSV58103015; called by muse, mutect2, varscan2
- SALL4 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.96); PolyPhen benign (0.235); catalogued as rs770743300, COSV53849955; called by muse, mutect2, varscan2
- SDR39U1 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771553538, COSV52158860; called by muse, mutect2
- SIK3 | c.529A>T p.N177Y (on ENST00000445177 / NM_001366686.2; = p.N183Y on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.373); catalogued as COSV52609242; called by muse, mutect2, varscan2
- SLC12A7 | c.545-1G>C p.X182_splice | Splice Site (SNP) | VAF 19/40 reads (48%) | catalogued as COSV99369418; called by muse, mutect2, varscan2
- SLC28A3 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs753167663, COSV66152474; called by muse, mutect2, varscan2
- SNX15 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200424255; called by muse, mutect2, varscan2
- SORCS2 | c.2027G>A p.R676Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.86); catalogued as rs748086651, COSV61163549; called by muse, mutect2, varscan2
- STAB1 | c.4321G>A p.A1441T | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as rs752951837, COSV58732432; called by muse, mutect2, varscan2
- SYNE2 | c.13319C>T p.S4440L | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs954767198; called by muse, mutect2
- TAOK2 | c.1634G>A p.R545Q | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.636); catalogued as rs755300621, COSV54233284, COSV54240011; called by muse, mutect2, varscan2
- TMEM131 | c.3458G>A p.R1153Q | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs762874750, COSV51770425; called by muse, mutect2, varscan2
- TNXB | c.8626C>G p.P2876A (on ENST00000647633; = p.P2629A on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV64473975; called by muse, mutect2, varscan2
- TRAF2 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as rs767031937, COSV56036376; called by muse, mutect2, varscan2
- TRIM67 | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as rs558077330, COSV64158168; called by muse, mutect2, varscan2
- TRIML2 | c.626C>A p.A209E | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV58714681, COSV58718852; called by muse, mutect2, varscan2
- TTN | c.46846C>G p.L15616V (on ENST00000591111; = p.L8192V on NM_003319.4) | Missense Mutation (SNP) | VAF 24/80 reads (30%) | PolyPhen probably damaging (0.996); catalogued as COSV59899223; called by muse, mutect2
- TTN | c.42593T>A p.I14198N (on ENST00000591111; = p.I6774N on NM_003319.4) | Missense Mutation (SNP) | VAF 80/188 reads (43%) | PolyPhen benign (0.26); catalogued as rs764388462, COSV59899241; called by muse, mutect2, varscan2
- UNC79 | c.7697C>A p.S2566* (on ENST00000393151 / NM_001346218.2; = p.S2389* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as COSV56375082; called by muse, mutect2, varscan2
- ZKSCAN3 | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.18); catalogued as rs1238486432, COSV52851635; called by muse, mutect2, varscan2
- ZNF358 | c.1186G>C p.V396L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as COSV99900416; called by muse, mutect2
- ZNF778 | c.2051G>A p.R684K | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as COSV60600636; called by muse, mutect2, varscan2
- ZNF835 | c.598G>A p.G200S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs528976354, COSV73379195; called by muse, mutect2, varscan2
- ZNF880 | c.663C>A p.F221L | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV69905783; called by muse, mutect2, varscan2
- ANKRD12 | c.2131_2132del p.L711Kfs*5 | Frame Shift Del (DEL) | VAF 111/318 reads (35%) | called by mutect2, pindel, varscan2
- MFSD10 | c.331_353del p.S111Gfs*48 | Frame Shift Del (DEL) | VAF 30/81 reads (37%) | called by mutect2, pindel, varscan2
- PCDH17 | c.2294del p.N765Mfs*16 | Frame Shift Del (DEL) | VAF 30/69 reads (43%) | called by mutect2, pindel, varscan2
- SERPINA7 | c.1006dup p.S336Ffs*17 | Frame Shift Ins (INS) | VAF 72/110 reads (65%) | called by mutect2, pindel, varscan2
- ABTB2 | c.976C>A p.R326= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV100130815, COSV100132259; called by muse, mutect2
- CDH13 | c.303C>G p.P101= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV51793172, COSV51818525; called by muse, mutect2
- CDH4 | c.1179C>T p.T393= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs369270154; called by muse, mutect2, varscan2
- CDK12 | c.3855T>C p.D1285= (on ENST00000447079 / NM_016507.4; = p.D1276= on NM_015083.3) | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV101420380; called by muse, mutect2, varscan2
- CHD5 | c.1194C>T p.D398= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV52408129; called by muse, mutect2, varscan2
- CNBD1 | c.678G>A p.S226= | Silent (SNP) | VAF 64/90 reads (71%) | catalogued as rs779115343, COSV72975904; called by muse, mutect2, varscan2
- CSMD2 | c.2553C>T p.I851= | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as rs1465315021, COSV53891614; called by muse, mutect2, varscan2
- CTNNA2 | c.1629C>A p.I543= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV58136291; called by muse, mutect2, varscan2
- CUX1 | c.2694C>T p.T898= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs966203796, COSV52891733; called by muse, mutect2, varscan2
- GABRR3 | c.1209A>C p.S403= | Silent (SNP) | VAF 53/129 reads (41%) | catalogued as COSV101512263; called by muse, mutect2, varscan2
- GALNT14 | c.1602C>G p.V534= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs1274769856, COSV61102602; called by muse, mutect2, varscan2
- GGN | c.258T>G p.P86= | Silent (SNP) | VAF 45/62 reads (73%) | catalogued as COSV53056039; called by muse, mutect2, varscan2
- GJD4 | c.420G>A p.S140= | Silent (SNP) | VAF 5/8 reads (63%) | catalogued as rs770953239, COSV100397130; called by muse, mutect2
- GRB14 | c.843C>T p.S281= | Silent (SNP) | VAF 41/109 reads (38%) | catalogued as rs762217333, COSV55735920; called by muse, mutect2, varscan2
- HELQ | c.225C>G p.L75= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as COSV55024201; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1008C>T p.F336= | Silent (SNP) | VAF 38/77 reads (49%) | catalogued as COSV57131288; called by muse, mutect2, varscan2
- ITPR1 | c.3586A>C p.R1196= (on ENST00000354582; = p.R1181= on NM_002222.7) | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as COSV56969703; called by muse, mutect2, varscan2
- KCNK16 | c.750C>T p.I250= | Silent (SNP) | VAF 16/23 reads (70%) | catalogued as COSV64677245; called by muse, mutect2, varscan2
- KCTD11 | c.678G>T p.R226= (on ENST00000333751 / NM_001363642.1; = p.R187= on NM_001002914.2) | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV50134149; called by muse, mutect2, varscan2
- KCTD3 | c.687C>T p.I229= | Silent (SNP) | VAF 35/71 reads (49%) | catalogued as rs1002990070, COSV52064306; called by muse, mutect2, varscan2
- KDM4C | c.1392A>T p.I464= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV67183800; called by muse, mutect2, varscan2
- KIAA0513 | c.846C>T p.D282= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as rs745333847, COSV50740625; called by muse, mutect2, varscan2
- KLHL34 | c.1623C>T p.I541= | Silent (SNP) | VAF 15/18 reads (83%) | catalogued as COSV65278736; called by muse, mutect2, varscan2
- KRT74 | c.285C>A p.G95= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV59770596; called by muse, mutect2, varscan2
- KRTAP19-1 | c.174C>A p.G58= | Silent (SNP) | VAF 49/98 reads (50%) | catalogued as COSV66860979; called by muse, mutect2, varscan2
- LRIT1 | c.1863C>T p.Y621= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV64511978; called by muse, mutect2, varscan2
- NR2E1 | c.99C>T p.C33= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as COSV64561434; called by muse, mutect2, varscan2
- PCDHA7 | c.1923C>T p.D641= | Silent (SNP) | VAF 33/68 reads (49%) | catalogued as rs1554135806, COSV65342003; called by muse, mutect2, varscan2
- PCDHAC2 | c.486G>A p.A162= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs199714982, COSV53838044; called by muse, mutect2, varscan2
- PCDHB12 | c.651C>T p.G217= | Silent (SNP) | VAF 60/118 reads (51%) | catalogued as rs561631495, COSV53393325; called by muse, mutect2, varscan2
- PIK3R3 | c.1236C>A p.G412= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV53104492; called by muse, mutect2, varscan2
- PMS2 | c.1242C>T p.D414= | Silent (SNP) | VAF 28/111 reads (25%) | catalogued as rs142839559; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- PNPLA7 | c.2658C>T p.R886= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as rs769607734, COSV52994592; called by muse, mutect2, varscan2
- POTEM | c.393G>A p.P131= | Silent (SNP) | VAF 89/138 reads (64%) | catalogued as rs756432876, COSV69154839; called by mutect2, varscan2
- PTPRT | c.369C>T p.Y123= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs571326580, COSV61962000; called by muse, mutect2, varscan2
- RHBG | c.267C>T p.S89= | Silent (SNP) | VAF 40/92 reads (43%) | catalogued as rs767588048, COSV54801946; called by muse, mutect2, varscan2
- RP1L1 | c.918C>T p.G306= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as rs763538477, COSV66751955; called by muse, mutect2
- RPL21 | c.90T>C p.Y30= | Silent (SNP) | VAF 53/112 reads (47%) | catalogued as rs371046119; called by muse, mutect2, varscan2
- RTP1 | c.60C>T p.S20= | Silent (SNP) | VAF 32/58 reads (55%) | catalogued as rs374423123; called by muse, mutect2, varscan2
- RXFP3 | c.1221C>T p.I407= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as rs780245177, COSV57504408, COSV57508152; called by muse, mutect2, varscan2
- RYR1 | c.12603C>T p.R4201= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs1273187654, COSV62089567; ClinVar: likely benign; called by muse, mutect2, varscan2
- SBK2 | c.369C>T p.Y123= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs200066533, COSV60013308; called by muse, mutect2, varscan2
- SDK2 | c.5013C>T p.L1671= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as rs1277758724, COSV66181665; called by muse, mutect2, varscan2
- SDR9C7 | c.519C>T p.C173= | Silent (SNP) | VAF 33/64 reads (52%) | catalogued as rs139321947; called by muse, mutect2, varscan2
- SLC13A5 | c.1335G>A p.P445= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as rs138802643; called by muse, mutect2, varscan2
- SOBP | c.342A>G p.S114= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV100432850; called by muse, mutect2
- SRRT | c.1305C>T p.A435= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs1307079534, COSV53815285; called by muse, mutect2, varscan2
- SYNE1 | c.24675G>A p.R8225= (on ENST00000367255 / NM_182961.4; = p.R8154= on NM_033071.3) | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV54912660; called by muse, mutect2, varscan2
- TBX5 | c.1518C>T p.H506= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs767955877, COSV59858598; called by muse, mutect2, varscan2
- USH2A | c.10467T>C p.A3489= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV100230251; called by muse, mutect2, varscan2
- UXS1 | c.894G>A p.A298= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs1395981710, COSV51675177; called by muse, mutect2, varscan2
- XKR6 | c.1341G>A p.T447= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs200587252, COSV58654171; called by muse, mutect2, varscan2
- ZMYM1 | c.1032T>C p.V344= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV63250497; called by muse, mutect2, varscan2
- KLRA1P | n.355A>T | RNA (SNP) | VAF 21/47 reads (45%) | called by muse, mutect2, varscan2
- MIR522 | n.79G>A | RNA (SNP) | VAF 29/139 reads (21%) | catalogued as rs377484755; called by muse, mutect2, varscan2
- SSPOP | n.1195C>A | RNA (SNP) | VAF 35/51 reads (69%) | catalogued as rs780591674, COSV50486488; called by muse, mutect2, varscan2
